Somatic mutation profile of tumor specimen 0DMEUI from CCDI case PBCAMH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Gastrointestinal stromal tumor, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 15.8 years (5,764 days).
Specimen 0DMEUI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e8e85e5-7001-4b12-a4b2-bb3744e97a67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMEUM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5242996-a0f7-4747-9144-35dbc9cb9ed4

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HS6ST2 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 32/511 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs868604170; called by muse, mutect2
- IGDCC4 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs949337865, COSV61539114; called by muse, mutect2
- LTBP1 | c.2939G>A p.R980Q (on ENST00000404816 / NM_206943.4; = p.R654Q on NM_000627.4) | Missense Mutation (SNP) | VAF 23/640 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs868050283; called by muse, mutect2
- BCORL1 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 127/400 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MUC4 | c.13489G>A p.A4497T (on ENST00000463781 / NM_018406.7; = p.A261T on NM_004532.6) | Missense Mutation (SNP) | VAF 64/691 reads (9%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.012); called by muse, mutect2
- PAH | c.1038G>T p.G346= | Silent (SNP) | VAF 186/438 reads (42%) | catalogued as CD931037; called by muse, mutect2, varscan2
- MCOLN3 | c.946-9T>C | Intron (SNP) | VAF 16/289 reads (6%) | called by muse, mutect2
